Somatic mutation profile of tumor specimen 0DVZEI from CCDI case PBCMUS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (635 days).
Specimen 0DVZEI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df585a75-b3f5-40e0-a79c-feda2588ed85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZEB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deeade62-939c-4690-bfc1-ab9ce9ea8adf

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLA2G5 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs772024718, COSV64283173; called by muse, mutect2, varscan2
- SRMS | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752069368, COSV53917168; called by muse, mutect2, varscan2
- RABGGTA | c.1147+69G>A | Intron (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ZBTB47 | c.*63C>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2, varscan2
